Somatic mutation profile of tumor specimen cab796c6-0129-43cf-bd27-7da395 (aliquot cab796c6-0129-43cf-bd27-7da395_D6_1) from CPTAC case 11BR015, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.9 years (21,869 days).
Specimen cab796c6-0129-43cf-bd27-7da395: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e7ab78c-9306-401d-8648-364d1b0a8423.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4a92b6da-eff2-46b8-b17e-97a19c (Blood Derived Normal), aliquot 4a92b6da-eff2-46b8-b17e-97a19c_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b95de995-d2ab-4f17-9ca7-41d64a5ed4aa

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 20, Silent 9, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARMIL2 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 29/40 reads (73%) | catalogued as rs1180363542, COSV58025102; called by muse, mutect2, varscan2
- DNASE1L1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 142/307 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1469827058; called by muse, mutect2, varscan2
- INPP4A | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs755959497; called by muse, mutect2, varscan2
- KMT2A | c.5029G>A p.E1677K | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV63295197; called by muse, mutect2, varscan2
- PLA1A | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs921530538, COSV56333607; called by muse, mutect2, varscan2
- PLB1 | c.3841C>T p.H1281Y | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753016827; called by muse, mutect2, varscan2
- QRFPR | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs775622291; called by muse, mutect2, varscan2
- RYR2 | c.12373G>A p.V4125I | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.153); catalogued as rs775417996, COSV63658123, COSV63663747, COSV63724087; called by muse, mutect2, varscan2
- SP3 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59466430; called by muse, mutect2, varscan2
- WDFY4 | c.2275C>T p.R759W | Missense Mutation (SNP) | VAF 162/380 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1386231369, COSV57436245; called by muse, mutect2, varscan2
- ZNF836 | c.2704C>T p.R902C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs201384689, COSV59087337; called by muse, mutect2
- ABCA1 | c.6344C>A p.A2115E | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AC048338.2 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ARAP1 | c.680-1G>C p.X227_splice | Splice Site (SNP) | VAF 60/138 reads (43%) | called by muse, mutect2, varscan2
- CARMIL2 | c.2405A>C p.E802A | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- DENND2B | c.3318G>T p.Q1106H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- FAM189A1 | c.552C>A p.N184K | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GALNT18 | c.1417-1G>A p.X473_splice | Splice Site (SNP) | VAF 23/207 reads (11%) | called by muse, mutect2
- GPR50 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- HDGFL2 | c.2004C>A p.D668E (on ENST00000616600 / NM_001001520.3; = p.D667E on NM_032631.4) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.06); called by muse, mutect2
- IFT172 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 148/259 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- LAMA3 | c.4253_4266del p.D1418Gfs*14 | Frame Shift Del (DEL) | VAF 225/541 reads (42%) | called by mutect2, pindel*, varscan2*
- TAB3 | c.728A>G p.Q243R | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- TTBK1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ENTHD1 | c.81C>T p.N27= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs146928757; called by muse, mutect2, varscan2
- MSRA | c.399G>C p.L133= | Silent (SNP) | VAF 35/52 reads (67%) | catalogued as rs1187189339, COSV100412771; called by muse, mutect2, varscan2
- PCDHB1 | c.1704C>T p.N568= | Silent (SNP) | VAF 117/279 reads (42%) | catalogued as rs137984585, COSV60629843, COSV60631383; called by muse, mutect2, varscan2
- RTN1 | c.1341A>T p.P447= | Silent (SNP) | VAF 55/131 reads (42%) | called by muse, mutect2, varscan2
- TCHH | c.531G>A p.R177= | Silent (SNP) | VAF 113/232 reads (49%) | catalogued as rs866421485; called by muse, mutect2, varscan2
- TP53INP2 | c.303C>T p.I101= | Silent (SNP) | VAF 90/243 reads (37%) | catalogued as COSV66351132; called by muse, mutect2, varscan2
- TTN | c.83655C>A p.I27885= (on ENST00000591111; = p.I20461= on NM_003319.4) | Silent (SNP) | VAF 34/146 reads (23%) | called by muse, mutect2, varscan2
- UTF1 | c.990C>T p.A330= | Silent (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- VXN | c.204C>T p.G68= | Silent (SNP) | VAF 50/166 reads (30%) | catalogued as COSV59685585; called by muse, mutect2, varscan2
